Surgical pathology report (de-identified scan), TCGA case TCGA-06-2557, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2557-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

TCGA-06-2557

CLINICAL HISTORY

The patient is a [REDACTED] presenting with mental status changes. He has a past medical history of carcinoma of the [REDACTED] and recent hospitalization for [REDACTED]. Neuroimaging revealed several ring-enhancing brain lesions with edema.

OPERATIVE DIAGNOSES

Brain tumor

Operation/Specimen: A: Right frontal tumor

?: Right frontal brain tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, right frontal tumor, excision: Glioblastoma (WHO Grade IV) (see comment).

COMMENT

Sections show a biphasic glioma composed of densely cellular areas of gemistocytic astrocytes and more densely cellular areas of less differentiated cells. Frequent mitoses, vascular proliferation and pseudopalisading necrosis are present. The Ki-67 labeling index is up to approximately 30%. A p53 immunohistochemical stain is negative. MGMT promoter methylation testing is pending and will be reported in a procedure addendum.

INTRA-OPERATIVE CONSULTATION

A. Right frontal tumor:

1. Touch prep and smears: Malignant glioma (C/W glioblastoma). Touch preparation smears performed at [REDACTED] and results reported to the [REDACTED].
2. Frozen sections: Glioblastoma. [REDACTED]

[page 2 of 2]
GROSS DESCRIPTION

Received fresh, three fragments, 0.9 cm. in aggregate. Semi firm, pinkish-grey, glistening. In total, A1 and A2, frozen tissue A3.

B.
SPECIMEN: Right frontal brain tumor.
FIXATIVE: Formalin.
GENERAL: Received are two irregular, gray-white to tan fragments of brain tissue 1.0 cm. in greatest dimensions and 2.5 x 1.5 x 1.3 cm. Sectioned and all submitted.
SECTIONS: B1 smaller fragment; B2,B4 large fragment.

ICD-9(s):
239.6 239.6

Histo Data

Part A: Right frontal tumor

Taken:	Received:
Stain/cnt	Block Ordered Comment
H/E x 1	1
H/E x 1	2
H/E x 1	3
GMT x 1	3
MIB1-DA x 1	3
P53DO7 x 1	3

Part B: Right frontal brain tumor, excision biopsy

Taken:	Received:
Stain/cnt	Block Ordered Comment
H/E x 1	1
H/E x 1	2
H/E x 1	3
H/E x 1	4

*** End of Report ***

Source: NCI Genomic Data Commons file 840771fd-ab84-40d0-9a19-e0cee6a1c7c1 (TCGA-06-2557.D3ED0551-1EC4-4146-AB0C-AF6371A4C708.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).